Gene-level copy-number profile of tumor specimen C3N-00317-04 from CPTAC case C3N-00317, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 74.2 years (27,092 days).
Specimen C3N-00317-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4b515b96-f467-4ece-b6a2-30e2dbd803d0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00317-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/2ea5e098-0d6f-4eb7-9b72-2e75bfb4df5a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 352; copy number 1: 8,956; copy number 2: 41,370; copy number 3: 5,825; copy number 4: 1,900.

Homozygous deletions (total copy number 0; autosomes only): 352 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:51,865,050–51,865,535, 1 gene (within-gene range 0–2): DUTP7.
- chr9:64,817,870–64,836,341, 1 gene: AL359955.1.
- chr13:48,975,912–49,209,779, 5 genes (within-gene range 0–2): FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1.
- chr14:18,333,726–22,552,156, 332 genes (within-gene range 0–1) (broad region; genes not listed).
- chr16:33,577,502–33,622,547, 1 gene (within-gene range 0–3): AC142384.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,956. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
